Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8342, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8342-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

- 1: SP: KIDNEY AND URETER, LEFT; NEPHRECTOMY
- 2: SP: LYMPH NODES, PARA-AORTIC; REGIONAL RESECTION
- 3: SP: ADRENAL, LEFT; ADRENALECTOMY
- 4: SP: LYMPH NODES, SUPRA-HILAR; REGIONAL RESECTION

DIAGNOSIS:

1. SP: KIDNEY AND URETER, LEFT; NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Chromophobe type
with extensive necrosis and degenerative changes

Tumor Size:

Greatest diameter is 14 cm.

Local Invasion (for renal cortical types):

Extends into renal pelvis

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild patchy chronic interstitial inflammation

Adrenal Gland:

Not identified

See part 3

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

2. SP: LYMPH NODES, PARA-AORTIC; REGIONAL RESECTION:

Lymph Nodes:

Not involved

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Number of nodes examined:9

3. ADRENAL, LEFT; ADRENALECTOMY:
- Benign adrenal gland

4. SP: LYMPH NODES, SUPRA-HILAR; REGIONAL RESECTION:

Lymph Nodes:

Not involved

Number of nodes examined:4

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh labeled "Left kidney and ureter" and consists of a kidney with a renal mass, attached ureter, renal vessels and perinephric fat weighing 1,384 g in total. The kidney and renal mass total 18 x 15.7 x 8.9 cm, with the normal distinguishable portion of the kidney measuring 15 x 4.5 x 3 cm. The attached ureter measures 10.2 cm in length and 0.4 cm in diameter, and is opened to reveal a pink-tan grossly unremarkable mucosa. The attached renal vessels appear pink-tan patent and grossly uninvolved by tumor. No adrenal gland is identified. The renal capsular surface is smooth pink-tan, with ill defined areas of subcapsular hemorrhage noted. The margin has been inked black. The kidney is bisected to reveal a large circumscribed tumor with areas of necrosis measuring 14 x 13 x 7.8 cm, which abuts the renal pelvis, and does not appear to grossly involve the inked perinephric fat. A 1.9 cm bulging red green smooth area is identified protruding through an irregular defect at the mucosal surface of the renal pelvis. On sectioning, both the renal pelvis and renal sinus appear grossly uninvolved by tumor. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.7 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections. Photographs have been taken.

Summary of sections:

UVM -- ureteral and vessel margins
RP -- renal pelvis representative sections
RS--representative section renal sinus
RST -representative sections tumor
TK-representative section tumor with adjacent uninvolved kidney
BA -- bulging area at renal pelvis
TWF -- tumor with capsular surface and perinephric fat
NK-normal kidney

2). The specimen is received in formalin, labeled "Para-aortic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.9 to 3.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes (blocks 6 and 7 =same node, 8 and 9 = same node)

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

3). The specimen is received in formalin, labeled "Left adrenal gland". It consists of an adrenal gland with attached unremarkable fatty tissue measuring 7.5 x 2.5 x 1.5 cm, and weighs 16.5 grams after fixation. The specimen is inked in black and serially sectioned to reveal a homogeneous golden bright, yellow firm cut surface. No lymph nodes are identified. Entirely submitted. The specimen is photographed.

Summary of sections:
SS-serial sections

4). The specimen is received in formalin, labeled "Supra hilar lymph nodes" and consists of 2 possible firm lymph nodes measuring 1 and 1.7 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:
LN- lymph nodes

Summary of Sections:

Part 1: SP: KIDNEY AND URETER, LEFT; NEPHRECTOMY

Block	Sect. Site	PCs
1	ba	1
1	nk	1
1	rp	1
1	rs	1
6	rst	6
1	tk	1
1	twf	1
1	uvm	1

Part 2: SP: LYMPH NODES, PARA-AORTIC; REGIONAL RESECTION

Block	Sect. Site	PCs
8	BLN	16
1	LN	3

Part 3: SP: ADRENAL, LEFT; ADRENALECTOMY

Block	Sect. Site	PCs
10	SS	13

Part 4: SP: LYMPH NODES, SUPRA-HILAR; REGIONAL RESECTION

Block	Sect. Site	PCs
1	LN	2

Source: NCI Genomic Data Commons file 3ce4d964-b894-41f1-8591-e3224967226e (TCGA-KL-8342.AC7B5DCD-A2BA-4BB7-8BD8-D5EB0B9E01E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).